TCGA case TCGA-AG-3584 — Rectum Adenocarcinoma (TCGA-READ)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Adenomas and Adenocarcinomas; Primary site: Rectum; Tissue source site: Indivumed. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/b2c48624-a483-4b1d-9155-c0c80ed2f7a0

Demographics
Sex at birth: male; Country of residence at enrollment: Germany; Age at index: 60 years; Vital status: Dead; Days to death: 730 days (2.0 years).

Diagnoses (1)
1. Adenocarcinoma, NOS: ICD-O-3 morphology code: 8140/3; ICD-10 code: C20; Tissue or organ of origin: Rectum, NOS; Site of resection or biopsy: Rectum, NOS; Classification of tumor: primary; Age at diagnosis: 60.8 years (22,189 days); Year of diagnosis: 2008; AJCC staging edition: 6th; AJCC pathologic T: T3; AJCC pathologic N: N2; AJCC pathologic M: M1; AJCC pathologic stage: Stage IV; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Residual disease: R2; Days to last follow up: 730 days (2.0 years).
   Pathology details: Circumferential resection margin: 2; Lymph nodes positive: 20; Lymph nodes tested: 34; Lymphatic invasion present: Yes; Vascular invasion present: Yes.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Fluorouracil + Irinotecan + Leucovorin Calcium; Days to treatment start: 92 days; Days to treatment end: 274 days; Treatment outcome: Progressive Disease.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Fluorouracil + Leucovorin Calcium + Oxaliplatin; Days to treatment start: 335 days; Days to treatment end: 396 days (1.1 years); Treatment outcome: Progressive Disease.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Irinotecan; Days to treatment start: 427 days (1.2 years); Days to treatment end: 580 days (1.6 years); Treatment outcome: Progressive Disease.
   Recorded as not given: adjuvant Radiation Therapy, NOS.

Follow-up (2 entries)
- Days to follow up: 0 days; Disease response: With Tumor.
- Days to follow up: 730 days (2.0 years); Disease response: With Tumor.

Molecular and laboratory tests
- CEA: 36.7 ng/mL.

Family history
- Relative with cancer history: no.

Biospecimens (4 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-AG-3584-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Longest dimension: 1.4; Intermediate dimension: 1; Shortest dimension: 0.6.
  Slide TCGA-AG-3584-01A-01-BS1: Section location: Bottom; Percent tumor cells: 75; Percent tumor nuclei: 75; Percent normal cells: 15; Percent necrosis: 5; Percent stromal cells: 5.
  Slide TCGA-AG-3584-01A-01-TS1: Section location: Top; Percent tumor cells: 72; Percent tumor nuclei: 75; Percent normal cells: 15; Percent necrosis: 8; Percent stromal cells: 5.
- Sample TCGA-AG-3584-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Samples TCGA-AG-3584-10A, TCGA-AG-3584-10B (2 with the same recorded description): Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Histologic diagnosis: Rectal Adenocarcinoma; History neoadjuvant treatment: No; Prospective collection: No; Retrospective collection: Yes; Tumor status: With tumor; Lymph nodes examined: Yes; CEA level pretreatment: 36.7; Lymphovascular invasion indicator: Yes; KRAS gene analysis indicator: No; BRAF gene analysis indicator: No; History colon polyps: No; Mismatch rep proteins tested by IHC: No.
- Drug treatment 1: Pharmaceutical therapy drug name: Folinic acid; Treatment best response: Clinical Progressive Disease.
- Drug treatment 2: Pharmaceutical therapy drug name: 5-Fluorouracil; Treatment best response: Clinical Progressive Disease.
- Follow-up form: Lost to follow-up: No; Tumor status: With tumor; New tumor event diagnosis indicator: No.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: event (deceased), 730 days; disease-specific survival: event (death attributed to the disease, the Clinical Data Resource's approximation), 730 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 730 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-AG-3584-01A-01D-0819-01): tumor purity 0.77, ploidy 1.99, whole-genome doublings 0.
